TARGET case TARGET-30-PAUWED — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Other and ill-defined sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/378f5b37-a70a-5429-aa28-e9f9ac14cb89

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 0 years; Vital status: Dead; Days to death: 1,119 days (3.1 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C76.2; Tissue or organ of origin: Abdomen, NOS; Classification of tumor: primary; Age at diagnosis: 0.9 years (325 days); Year of diagnosis: 2012; Days to last follow up: 1,119 days (3.1 years); Cog neuroblastoma risk group: Intermediate Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 2B; Mitosis karyorrhexis index: Intermediate.
   Pathology details: Percent tumor nuclei: 80.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (1 entry)
- Days to follow up: 1,119 days (3.1 years); Days to first event: 1,119 days (3.1 years); First event: Death; Year of follow up: 2015.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PAUWED-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAUWED-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1119
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.19
- Histology: Favorable
- ICDO Description: Abdomen, NOS Abdominal wall, NOS Intra-abdominal site, NOS
